Somatic mutation profile of tumor specimen C3N-00709-01 (aliquot CPT0203850007) from CPTAC case C3N-00709, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen C3N-00709-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df23774-2720-44fc-bca6-575e332a775f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00709-71 (Blood Derived Normal), aliquot CPT0203890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d5a0e84-ba45-41e8-b7dd-ee5ba90faf28

The open-access MAF lists 64 somatic variants for this specimen: 51 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 9, Intron 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 70/465 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.393_395del p.N131del | In Frame Del (DEL) | VAF 70/371 reads (19%) | hotspot (GDC flag); catalogued as rs879254214; called by pindel, varscan2
- APCDD1L | c.1283T>A p.I428N | Missense Mutation (SNP) | VAF 113/534 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs149312027; called by muse, mutect2, varscan2
- ASB9 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs750343277; called by muse, mutect2, varscan2
- CCT8L2 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs773674246, COSV63461611; called by muse, mutect2, varscan2
- CD207 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 74/499 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs781983818, COSV69651938; called by muse, mutect2, varscan2
- CFHR5 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs775956342, COSV56818541; called by muse, mutect2
- CUL9 | c.6806G>A p.W2269* | Nonsense Mutation (SNP) | VAF 72/437 reads (16%) | catalogued as rs1258993354; called by muse, mutect2, varscan2
- EPHB6 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 137/769 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63891497; called by muse, mutect2, varscan2
- EXD3 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372867176; called by muse, mutect2, varscan2
- HHATL | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs773754543; called by muse, mutect2, varscan2
- IFNL2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs368918145; called by muse, mutect2, varscan2
- KCNN4 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200807029; called by muse, mutect2, varscan2
- LAMA2 | c.6574-1G>C p.X2192_splice | Splice Site (SNP) | VAF 48/330 reads (15%) | catalogued as COSV101370724; called by muse, mutect2, varscan2
- MEFV | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 108/726 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs104895119, CM035567, CM055424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLLT10 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs768627047; called by muse, mutect2, varscan2
- NAA16 | c.1548dup p.E517* | Frame Shift Ins (INS) | VAF 18/109 reads (17%) | catalogued as rs749241638; called by mutect2, varscan2
- NBPF11 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 74/1001 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1210117053; called by muse, varscan2
- PGBD5 | c.611G>A p.R204Q (on ENST00000525115; = p.R273Q on NM_001258311.2) | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.928); catalogued as rs745691276; called by muse, mutect2, varscan2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- PLXNA4 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 88/812 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs199571283, COSV58102572; called by muse, mutect2, varscan2
- PTPN13 | c.5497C>T p.R1833W (on ENST00000411767 / NM_080683.3; = p.R1814W on NM_006264.3) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747404195; called by muse, mutect2, varscan2
- SIGLEC14 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV55784412; called by mutect2, varscan2
- TMC4 | c.502C>T p.R168C (on ENST00000617472 / NM_001145303.3; = p.R162C on NM_144686.4) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764731755; called by muse, mutect2, varscan2
- TMEM132E | c.562C>T p.R188C (on ENST00000321639; = p.R278C on NM_001304438.2) | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs924629587; called by muse, mutect2
- TUBB1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 118/528 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.483); catalogued as rs1457142785, COSV99414101; called by muse, mutect2, varscan2
- AC011462.1 | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 134/726 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKAP6 | c.5437A>G p.T1813A | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ALX3 | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ANKRD30B | c.2305C>A p.L769I | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ATP11A | c.3066G>T p.L1022F | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.291); called by muse, mutect2
- CUL9 | c.6290G>A p.W2097* | Nonsense Mutation (SNP) | VAF 53/379 reads (14%) | called by muse, mutect2, varscan2
- DPYS | c.1378G>T p.G460W | Missense Mutation (SNP) | VAF 150/872 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTWD2 | c.821T>C p.L274S | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- EXT1 | c.1411A>G p.N471D | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HERC5 | c.2486A>T p.E829V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HSPD1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ITGAL | c.2642A>T p.N881I | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LMO3 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NOTCH2 | c.1238C>G p.T413R | Missense Mutation (SNP) | VAF 151/778 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PLEKHA8 | c.205_206dup p.Q69Hfs*6 | Frame Shift Ins (INS) | VAF 34/248 reads (14%) | called by mutect2, pindel, varscan2
- PTBP2 | c.79C>G p.L27V (on ENST00000426398 / NM_001300986.2; = p.L19V on NM_021190.4) | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTPRQ | c.1503G>A p.M501I (on ENST00000616559; = p.M459I on NM_001145026.2) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- RTN1 | c.2159A>G p.N720S | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SEC14L1 | c.1359T>A p.D453E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- STAB1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- SUGP1 | c.1317_1324del p.D439Efs*43 | Frame Shift Del (DEL) | VAF 53/375 reads (14%) | called by mutect2, pindel, varscan2
- TFE3 | c.806T>A p.I269N | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM26 | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 86/531 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSIG4 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- XKR5 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- AHI1 | c.3084A>G p.L1028= | Silent (SNP) | VAF 69/460 reads (15%) | catalogued as rs1373010213; called by muse, mutect2, varscan2
- CUL9 | c.6492G>A p.Q2164= | Silent (SNP) | VAF 131/945 reads (14%) | called by muse, mutect2, varscan2
- LYST | c.4381C>T p.L1461= | Silent (SNP) | VAF 93/513 reads (18%) | catalogued as COSV67711407; called by muse, mutect2, varscan2
- MAFB | c.465G>A p.L155= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- NAB2 | c.183C>T p.F61= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- NRXN3 | c.60G>A p.G20= | Silent (SNP) | VAF 51/470 reads (11%) | catalogued as rs926969351, COSV55326641; called by muse, mutect2, varscan2
- SENP6 | c.1456T>C p.L486= | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- WFDC11 | c.126C>T p.C42= | Silent (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.789C>T p.V263= | Silent (SNP) | VAF 27/407 reads (7%) | catalogued as rs753159242; called by muse, mutect2
- DPP10 | c.61-147059C>G | Intron (SNP) | VAF 54/463 reads (12%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18520G>T | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- ZFP36 | c.-12C>T | 5'UTR (SNP) | VAF 41/332 reads (12%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+923C>T | Intron (SNP) | VAF 59/459 reads (13%) | catalogued as rs768212375; called by muse, mutect2, varscan2
